Somatic mutation profile of tumor specimen TCGA-WK-A8XZ-01A (aliquot TCGA-WK-A8XZ-01A-11D-A37C-09) from TCGA case TCGA-WK-A8XZ, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of abdomen; Age at diagnosis: 56.0 years (20,460 days).
Specimen TCGA-WK-A8XZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a031b7ac-1326-4c2a-baf2-692d84fb372a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WK-A8XZ-10A (Blood Derived Normal), aliquot TCGA-WK-A8XZ-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/858e7dc5-cdcf-4135-b8ba-9023d532a578

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 6, Frame Shift Del 2, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH7 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as rs121913651, CM990893, COSV100806385; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.394A>G p.K132E | Missense Mutation (SNP) | VAF 11/13 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747342068, CM086989, CM973641, COSV52689323, COSV52708494, COSV52979406, COSV53353999; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ALDH1A3 | c.187G>T p.V63L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs758966858, COSV100320560; called by muse, mutect2, varscan2
- ALOX12B | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100047499; called by muse, mutect2, varscan2
- ECSCR | c.29G>A p.C10Y | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.838); catalogued as rs756483570, COSV101579667; called by muse, mutect2, varscan2
- FAM189B | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1471858792, COSV100617512; called by muse, mutect2
- KCNC2 | c.1724G>A p.C575Y | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.38); catalogued as rs1394426734, COSV100129479; called by muse, mutect2, varscan2
- LRP2 | c.12623C>A p.P4208H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99789595; called by muse, mutect2, varscan2
- MACF1 | c.16037G>C p.C5346S (on ENST00000372915; = p.C3279S on NM_012090.5) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as COSV99245856; called by muse, mutect2, varscan2
- MAGEC1 | c.3202G>A p.E1068K | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as rs199683263, COSV53573910; called by muse, mutect2, varscan2
- NKPD1 | c.2284G>A p.A762T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.9); PolyPhen benign (0.012); catalogued as COSV99674984; called by muse, mutect2, varscan2
- NLRP9 | c.131G>T p.W44L | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV60463217; called by muse, mutect2, varscan2
- NMD3 | c.269T>C p.L90P | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100664771; called by muse, mutect2, varscan2
- P4HA3 | c.1175+1G>A p.X392_splice | Splice Site (SNP) | VAF 13/35 reads (37%) | catalogued as COSV100525811; called by muse, mutect2, varscan2
- PCNX2 | c.3760T>C p.F1254L | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.298); catalogued as COSV50783299; called by muse, mutect2
- PLEC | c.8681G>C p.G2894A (on ENST00000322810 / NM_201380.4; = p.G2784A on NM_000445.5) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV100516853; called by muse, mutect2, varscan2
- THAP5 | c.865A>G p.I289V (on ENST00000415914 / NM_001130475.3; = p.I247V on NM_182529.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100542865; called by muse, mutect2, varscan2
- ALDH8A1 | c.1203del p.F402Lfs*7 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, pindel, varscan2
- MUC2 | c.1210G>C p.G404R | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.59); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- RB1 | c.1642_1666del p.K548Efs*55 | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | called by mutect2, varscan2
- ASH1L | c.4401C>T p.P1467= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV100853537; called by muse, mutect2, varscan2
- CAGE1 | c.2019T>C p.D673= (on ENST00000512086; = p.D537= on NM_205864.3) | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs934061421, COSV99699973; called by muse, mutect2, varscan2
- KRI1 | c.642C>T p.N214= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100470294; called by muse, mutect2, varscan2
- NIPAL3 | c.573C>T p.L191= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV99135410; called by muse, mutect2, varscan2
- SLC6A6 | c.306C>G p.G102= | Silent (SNP) | VAF 51/96 reads (53%) | catalogued as COSV100692369; called by muse, mutect2, varscan2
- THEMIS | c.1680C>T p.H560= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV100965475; called by muse, mutect2, varscan2
- B4GALNT1 | c.*1138C>A | 3'UTR (SNP) | VAF 13/34 reads (38%) | catalogued as rs759270517, COSV100247256; called by muse, mutect2, varscan2
